Somatic mutation profile of tumor specimen MMRF_2851_1_BM_CD138pos (aliquot MMRF_2851_1_BM_CD138pos_T1_KHS5U_L16581) from MMRF case MMRF_2851, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2851_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73b476e7-c56e-4ef6-b7b2-d9ba30c68866.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2851_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2851_1_PB_WBC_C2_KHS5U_L16675; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14d9e259-ce9e-4290-b160-12c22ed7bc42

The open-access MAF lists 137 somatic variants for this specimen: 46 protein-altering or splice-affecting, 14 silent, 77 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 43, Missense Mutation 41, Intron 15, Silent 14, 5'UTR 9, Nonsense Mutation 4, 5'Flank 4, 3'Flank 3, RNA 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC093246.1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as rs984975545, COSV51125252; called by muse, varscan2
- ALG3 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757896361; called by muse, mutect2, varscan2
- ANKRD30A | c.3154T>A p.L1052I (on ENST00000611781; = p.L996I on NM_052997.2) | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV64621311; called by muse, mutect2
- DYNC2H1 | c.5176C>T p.R1726* | Nonsense Mutation (SNP) | VAF 69/171 reads (40%) | catalogued as rs772321133, CM130524, COSV100518383; called by muse, mutect2, varscan2
- GRB14 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368925193; called by muse, mutect2, varscan2
- GRK1 | c.1397-1G>A p.X466_splice | Splice Site (SNP) | VAF 10/26 reads (38%) | catalogued as rs1250024621; called by muse, mutect2, varscan2
- HMCN1 | c.7493C>T p.T2498M | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.059); catalogued as rs760153934, COSV54897877; called by muse, mutect2, varscan2
- IGLL5 | c.97A>G p.M33V | Missense Mutation (SNP) | VAF 48/59 reads (81%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs753218010; called by muse, varscan2
- INSYN2A | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs375773085; called by muse, mutect2, varscan2
- KCND3 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56180221; called by muse, mutect2, varscan2
- KDM6A | c.508C>T p.H170Y | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100938516; called by muse, mutect2
- LRATD1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs754922303; called by muse, mutect2, varscan2
- LRRC7 | c.127C>T p.R43W (on ENST00000651989 / NM_001370785.2; = p.R10W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/171 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150507629; called by muse, mutect2, varscan2
- MXRA5 | c.5990C>A p.P1997H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV54234953; called by muse, mutect2
- NEFM | c.2075C>T p.S692L | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV55334179; called by muse, mutect2
- NES | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV63963291; called by muse, mutect2
- NPFFR2 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV58152479; called by muse, mutect2
- PNPLA8 | c.688T>A p.F230I | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1563983123; called by muse, mutect2
- SLC5A8 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs199610556; called by muse, mutect2, varscan2
- THG1L | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 22/187 reads (12%) | catalogued as rs747543478, COSV51453629; called by muse, mutect2, varscan2
- ZCCHC12 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs1297513818; called by muse, mutect2
- ZSWIM2 | c.671A>G p.E224G | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV54574540; called by muse, mutect2, varscan2
- ARHGEF10 | c.3919T>G p.Y1307D (on ENST00000398564; = p.Y1282D on NM_014629.4) | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- ASB6 | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C1QTNF12 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- CXCR4 | c.132C>G p.I44M | Missense Mutation (SNP) | VAF 19/213 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.426); called by muse, mutect2
- CYLC1 | c.439A>G p.I147V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDX52 | c.688C>G p.P230A | Missense Mutation (SNP) | VAF 101/253 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DOCK1 | c.3164A>G p.Y1055C | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ERMARD | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLRB | c.1122T>G p.D374E | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2
- GMPR | c.365A>T p.Q122L | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- GPR176 | c.1286A>C p.D429A | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- KIAA2012 | c.2072A>T p.Q691L | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT tolerated (0.1); called by muse, mutect2
- LRRN3 | c.895T>C p.S299P | Missense Mutation (SNP) | VAF 52/387 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MATN4 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 35/61 reads (57%) | PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MYCBP2 | c.4943C>T p.S1648F (on ENST00000357337; = p.S1686F on NM_015057.5) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, varscan2
- NRG1 | c.296T>G p.I99S | Missense Mutation (SNP) | VAF 95/189 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR6F1 | c.658T>C p.Y220H | Missense Mutation (SNP) | VAF 23/307 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.012); called by muse, mutect2
- SORCS1 | c.2718G>T p.E906D | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TBC1D2 | c.2544C>A p.Y848* (on ENST00000465784 / NM_001267571.2; = p.Y837* on NM_018421.4) | Nonsense Mutation (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2, varscan2
- TMEM132C | c.3281C>A p.P1094H | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.553); called by muse, mutect2
- ZCCHC12 | c.644T>G p.M215R | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- ZNF217 | c.2380C>T p.Q794* | Nonsense Mutation (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- ZNF404 | c.119C>A p.T40N | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); called by muse, varscan2
- ZNF689 | c.1217G>T p.C406F | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ABCA13 | c.11007T>C p.S3669= | Silent (SNP) | VAF 19/242 reads (8%) | called by muse, mutect2
- CMYA5 | c.9480A>T p.A3160= | Silent (SNP) | VAF 19/236 reads (8%) | called by muse, mutect2
- CSMD1 | c.6210G>A p.S2070= (on ENST00000520002; = p.S2069= on NM_033225.6) | Silent (SNP) | VAF 28/186 reads (15%) | catalogued as rs190880525, COSV59346155; called by muse, mutect2, varscan2
- GPRIN3 | c.1866G>A p.K622= | Silent (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- IGLL5 | c.81G>A p.L27= | Silent (SNP) | VAF 56/68 reads (82%) | catalogued as rs56055217, COSV73249379; called by muse, varscan2
- ITPRIPL1 | c.885C>A p.V295= (on ENST00000439118 / NM_001008949.3; = p.V303= on NM_178495.6) | Silent (SNP) | VAF 69/157 reads (44%) | called by muse, mutect2, varscan2
- LRG1 | c.189C>T p.P63= | Silent (SNP) | VAF 27/185 reads (15%) | catalogued as rs114455332; called by muse, mutect2, varscan2
- PCSK5 | c.4704G>A p.R1568= | Silent (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
- PRKD2 | c.615C>T p.H205= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- RNASEH1 | c.594G>A p.K198= | Silent (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- RYR3 | c.3909C>T p.S1303= | Silent (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2
- STMN3 | c.339C>T p.H113= | Silent (SNP) | VAF 7/166 reads (4%) | called by muse, mutect2
- TF | c.600C>A p.T200= | Silent (SNP) | VAF 16/205 reads (8%) | called by muse, mutect2
- TTN | c.5199G>A p.T1733= (on ENST00000591111; = p.T1687= on NM_003319.4) | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as rs1244676379, COSV100600655, COSV59901276; called by muse, mutect2
- AC068473.1 | n.667C>G | RNA (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
- AGMO | c.1263+59252T>G | Intron (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- AGPAT3 | c.*205A>G | 3'UTR (SNP) | VAF 23/108 reads (21%) | called by muse, mutect2, varscan2
- AMER2 | chr13:25168239 G>A | 3'Flank (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- ANXA11 | c.*414G>A | 3'UTR (SNP) | VAF 96/227 reads (42%) | catalogued as rs867030273; called by muse, mutect2, varscan2
- ASAH1 | c.*66A>T | 3'UTR (SNP) | VAF 43/170 reads (25%) | called by muse, mutect2, varscan2
- AZIN2 | c.*58G>C | 3'UTR (SNP) | VAF 15/107 reads (14%) | catalogued as COSV99613213, COSV99613311; called by mutect2, varscan2
- AZIN2 | c.*63_*71del | 3'UTR (DEL) | VAF 14/109 reads (13%) | called by mutect2, pindel, varscan2
- BCL2L11 | c.*45T>C | 3'UTR (SNP) | VAF 44/216 reads (20%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021345 C>A | 5'Flank (SNP) | VAF 59/159 reads (37%) | called by muse, varscan2
- BCL7A | chr12:122021408 T>C | 5'Flank (SNP) | VAF 78/174 reads (45%) | catalogued as COSV104379334; called by muse, varscan2
- CASKIN1 | c.*463G>A | 3'UTR (SNP) | VAF 45/93 reads (48%) | catalogued as rs1166917689; called by muse, mutect2, varscan2
- CCDC93 | c.*2196G>A | 3'UTR (SNP) | VAF 53/104 reads (51%) | catalogued as rs950002840; called by muse, mutect2, varscan2
- CDH8 | c.*927T>G | 3'UTR (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- CLEC3A | c.*898T>A | 3'UTR (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- CLEC5A | c.*1518A>T | 3'UTR (SNP) | VAF 7/155 reads (5%) | called by muse, mutect2
- CYP26B1 | c.*2435C>T | 3'UTR (SNP) | VAF 17/173 reads (10%) | called by muse, mutect2, varscan2
- DCX | c.*1726T>G | 3'UTR (SNP) | VAF 29/92 reads (32%) | called by muse, mutect2, varscan2
- DGKG | c.144+43T>C | Intron (SNP) | VAF 14/180 reads (8%) | catalogued as rs747156963; called by muse, mutect2
- DXO | c.948+30G>C | Intron (SNP) | VAF 9/137 reads (7%) | called by muse, mutect2
- EOLA2 | c.*161del | 3'UTR (DEL) | VAF 58/220 reads (26%) | called by mutect2, varscan2
- EPHA5 | c.*2272G>C | 3'UTR (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- FAM182B | n.471G>T | RNA (SNP) | VAF 41/129 reads (32%) | catalogued as COSV100901784; called by muse, mutect2, varscan2
- FAM199X | c.*2758T>C | 3'UTR (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- FMNL1 | c.969+64A>G | Intron (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- FMO2 | c.*1223G>A | 3'UTR (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2
- FRMPD4 | c.-26G>A | 5'UTR (SNP) | VAF 40/122 reads (33%) | catalogued as rs777325845, COSV101043594; called by muse, mutect2, varscan2
- GALNT17 | c.-197G>A | 5'UTR (SNP) | VAF 30/188 reads (16%) | catalogued as rs1031642397; called by muse, mutect2, varscan2
- GAS8 | c.90+1203T>G | Intron (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- GATAD2B | c.*4180G>A | 3'UTR (SNP) | VAF 75/148 reads (51%) | called by muse, mutect2, varscan2
- GFOD1 | c.*1169A>C | 3'UTR (SNP) | VAF 5/22 reads (23%) | called by muse, varscan2
- GPALPP1 | c.-111T>C | 5'UTR (SNP) | VAF 21/304 reads (7%) | called by muse, mutect2
- GPR158 | c.*2478A>T | 3'UTR (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- GRM6 | c.2125-173C>A | Intron (SNP) | VAF 51/111 reads (46%) | called by muse, mutect2
- GUCA1A | c.-90C>T | 5'UTR (SNP) | VAF 17/86 reads (20%) | catalogued as rs765245233; called by muse, mutect2, varscan2
- HDAC2 | c.*4818_*4820del | 3'UTR (DEL) | VAF 6/45 reads (13%) | catalogued as rs1320628753; called by pindel, varscan2
- HS3ST3B1 | c.*2675C>T | 3'UTR (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- ISCA1 | c.*1252T>G | 3'UTR (SNP) | VAF 53/280 reads (19%) | called by muse, mutect2, varscan2
- ITPRID2 | c.*828C>A | 3'UTR (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- KLHL4 | c.-8C>T | 5'UTR (SNP) | VAF 14/288 reads (5%) | catalogued as COSV100908980; called by muse, mutect2
- LRIG1 | c.-266C>T | 5'UTR (SNP) | VAF 13/87 reads (15%) | catalogued as rs1401612355; called by muse, mutect2, varscan2
- LRRTM4 | c.*90C>T | 3'UTR (SNP) | VAF 5/49 reads (10%) | catalogued as COSV69152108; called by mutect2, varscan2
- MAP4K4 | chr2:101893411 G>A | 3'Flank (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- MBTPS2 | c.970+3355T>A | Intron (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- MCM5 | c.*287G>T | 3'UTR (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- MPPED2 | c.*3192T>A | 3'UTR (SNP) | VAF 68/142 reads (48%) | called by muse, mutect2, varscan2
- MUL1 | c.*1T>C | 3'UTR (SNP) | VAF 20/82 reads (24%) | catalogued as rs755864928; called by muse, mutect2, varscan2
- NCKAP5 | c.341+7959G>T | Intron (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- NKX3-2 | c.*809G>T | 3'UTR (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- NLRP5 | c.566-9C>G | Intron (SNP) | VAF 28/375 reads (7%) | catalogued as rs1481623193; called by muse, mutect2
- OSBP2 | c.645-9573G>T | Intron (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- PATZ1 | chr22:31347321 G>T | 5'Flank (SNP) | VAF 20/146 reads (14%) | called by muse, mutect2, varscan2
- PLPPR5 | c.-94C>A | 5'UTR (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- RFLNB | c.*2382C>T | 3'UTR (SNP) | VAF 19/67 reads (28%) | catalogued as rs1272289407; called by muse, mutect2, varscan2
- RNF157 | c.*1540G>A | 3'UTR (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- SEMA3D | c.*3466T>C | 3'UTR (SNP) | VAF 11/56 reads (20%) | called by mutect2, varscan2
- SFXN4 | c.111+231C>A | Intron (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- SIKE1 | c.*1C>T | 3'UTR (SNP) | VAF 79/301 reads (26%) | called by muse, mutect2, varscan2
- SLC16A14 | c.*1053T>G | 3'UTR (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- SLC38A2 | c.116+67A>G | Intron (SNP) | VAF 56/266 reads (21%) | called by muse, mutect2, varscan2
- SLC38A7 | c.*1664C>T | 3'UTR (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
- SLC7A1 | c.*4556A>C | 3'UTR (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- SMIM30 | c.-30+212C>G | Intron (SNP) | VAF 7/107 reads (7%) | called by muse, mutect2
- SORT1 | c.*4434G>A | 3'UTR (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- SPOCK1 | c.*2591C>T | 3'UTR (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- SPOPL | c.*1068G>A | 3'UTR (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- SPRYD3 | c.*491G>T | 3'UTR (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- TARBP2 | chr12:53500860 G>A | 5'Flank (SNP) | VAF 32/104 reads (31%) | called by muse, varscan2
- TDGF1P3 | n.2114A>C | RNA (SNP) | VAF 49/184 reads (27%) | called by muse, mutect2, varscan2
- TMEM92 | c.*649G>A | 3'UTR (SNP) | VAF 8/178 reads (4%) | catalogued as rs1397957242; called by muse, mutect2
- TUBB3 | c.166+23C>T | Intron (SNP) | VAF 16/314 reads (5%) | called by muse, mutect2
- UGT1A7 | c.855+8790C>T | Intron (SNP) | VAF 87/192 reads (45%) | called by muse, mutect2, varscan2
- WNK3 | c.*3910G>A | 3'UTR (SNP) | VAF 16/105 reads (15%) | called by muse, mutect2, varscan2
- YAF2 | c.*357G>C | 3'UTR (SNP) | VAF 4/86 reads (5%) | catalogued as rs1166826104; called by muse, mutect2
- ZFYVE19 | c.-475T>G | 5'UTR (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- ZNF157 | c.-38T>A | 5'UTR (SNP) | VAF 49/188 reads (26%) | called by muse, mutect2, varscan2
- ZNF207 | chr17:32373935 C>T | 3'Flank (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
